Somatic mutation profile of cancer-model specimen HCM-CSHL-0665-C24-85M (3D Organoid, passage 7; aliquot HCM-CSHL-0665-C24-85M-01D-A88G-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0665-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 73.8 years (26,959 days).
Specimen HCM-CSHL-0665-C24-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e511890-c780-4e6d-80e8-d386c5bc6945.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0665-C24-11A (Solid Tissue Normal), aliquot HCM-CSHL-0665-C24-11A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/294e7251-79dd-435c-a331-987d27b5cf3b

The open-access MAF lists 166 somatic variants for this specimen: 117 protein-altering or splice-affecting, 39 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 39, Nonsense Mutation 8, Intron 6, Frame Shift Del 4, Splice Site 2, 5'UTR 1, 5'Flank 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 87/253 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV57246601, COSV57252959; called by muse, mutect2, varscan2
- MAP2K4 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 105/105 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62254942, COSV62259088; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 243/388 reads (63%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.1712C>T p.S571L (on ENST00000326724 / NM_001080395.3; = p.S468L on NM_004920.2) | Missense Mutation (SNP) | VAF 550/550 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs761477063; called by muse, mutect2, varscan2
- ADCY6 | c.1292A>G p.Y431C | Missense Mutation (SNP) | VAF 132/448 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57171037; called by muse, mutect2, varscan2
- CACNA1I | c.4397G>A p.R1466Q | Missense Mutation (SNP) | VAF 141/360 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.193); catalogued as rs1010942110, COSV60804920, COSV60822079; called by muse, mutect2, varscan2
- CD5L | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 322/478 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145458344, COSV63821515; called by muse, mutect2, varscan2
- CDHR3 | c.2147T>A p.I716N | Missense Mutation (SNP) | VAF 307/670 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100488116; called by muse, mutect2, varscan2
- CHD9 | c.6658G>A p.V2220I | Missense Mutation (SNP) | VAF 244/517 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.293); catalogued as rs759268082; called by muse, mutect2, varscan2
- COL12A1 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV59400723; called by muse, mutect2, varscan2
- DDX5 | c.440_441+2del p.X147_splice | Splice Site (DEL) | VAF 222/224 reads (99%) | catalogued as rs782442161; called by mutect2, pindel, varscan2
- DNAH11 | c.10036C>T p.R3346* | Nonsense Mutation (SNP) | VAF 109/393 reads (28%) | catalogued as rs773851007, COSV60970262; called by muse, mutect2, varscan2
- DSG1 | c.633C>G p.I211M | Missense Mutation (SNP) | VAF 169/368 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0.304); catalogued as COSV57139456; called by muse, mutect2, varscan2
- FGF21 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 192/615 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs375785872; called by muse, mutect2, varscan2
- FOXP4 | c.782C>T p.S261L (on ENST00000307972 / NM_001012426.1; = p.S260L on NM_138457.3) | Missense Mutation (SNP) | VAF 225/639 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as rs755812624; called by muse, mutect2, varscan2
- FRY | c.8041G>A p.E2681K | Missense Mutation (SNP) | VAF 363/612 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1372617736, COSV66573028; called by muse, mutect2, varscan2
- FZD3 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 151/269 reads (56%) | SIFT tolerated (0.39); PolyPhen benign (0.341); catalogued as rs372290611; called by muse, mutect2, varscan2
- GCM1 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 121/342 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99452399; called by muse, mutect2, varscan2
- GLS | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 140/498 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs758103656; called by muse, mutect2, varscan2
- HSD17B14 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 232/648 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs948123523; called by muse, mutect2, varscan2
- IGLV3-10 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 196/321 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as rs376476919; called by muse, mutect2, varscan2
- INTS14 | c.1483G>A p.E495K (on ENST00000313182 / NM_001366360.2; = p.E416K on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 226/416 reads (54%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1406942868, COSV56012534; called by muse, mutect2, varscan2
- KIAA1109 | c.3321G>C p.K1107N | Missense Mutation (SNP) | VAF 158/158 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs772064200, COSV99145872, COSV99151199; called by muse, mutect2, varscan2
- KIF1A | c.4495G>A p.D1499N (on ENST00000320389 / NM_001379639.1; = p.D1491N on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 103/358 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.268); catalogued as rs1298786851, COSV57500041; called by muse, mutect2, varscan2
- LARS2 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 130/336 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV55527278; called by muse, mutect2, varscan2
- MAP3K19 | c.1888C>G p.L630V | Missense Mutation (SNP) | VAF 115/367 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs1237318802; called by muse, mutect2, varscan2
- MAST3 | c.3193C>T p.R1065W | Missense Mutation (SNP) | VAF 239/405 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs766465489; called by muse, mutect2, varscan2
- MBD3L2B | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 57/509 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as rs750820517; called by muse, mutect2, varscan2
- NALCN | c.116A>C p.H39P | Missense Mutation (SNP) | VAF 86/277 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as COSV51943464; called by muse, mutect2, varscan2
- NEPRO | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 93/312 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs780427753; called by muse, mutect2, varscan2
- NLRP11 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 114/354 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV64085963; called by muse, mutect2, varscan2
- OR51A7 | c.441T>G p.I147M | Missense Mutation (SNP) | VAF 25/651 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV63788618; called by muse, mutect2
- OR8B3 | c.260C>G p.S87* | Nonsense Mutation (SNP) | VAF 105/210 reads (50%) | catalogued as rs1226722677; called by muse, mutect2, varscan2
- OR8D2 | c.756del p.F252Lfs*4 | Frame Shift Del (DEL) | VAF 130/305 reads (43%) | catalogued as rs1238695261, COSV62488687; called by mutect2, pindel, varscan2
- PCDHB9 | c.1364C>G p.S455C | Missense Mutation (SNP) | VAF 450/451 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as COSV53377597; called by muse, mutect2, varscan2
- PLCL1 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as COSV70825024; called by muse, mutect2, varscan2
- PREX2 | c.3685G>A p.V1229I | Missense Mutation (SNP) | VAF 122/505 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs530869739, COSV55765733; called by muse, mutect2, varscan2
- ROBO1 | c.4217C>T p.A1406V | Missense Mutation (SNP) | VAF 143/346 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs1293482709; called by muse, mutect2, varscan2
- RYR2 | c.13892A>T p.D4631V | Missense Mutation (SNP) | VAF 79/283 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM146712; called by muse, mutect2
- SAPCD1 | c.140G>C p.R47T | Missense Mutation (SNP) | VAF 195/507 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65173497; called by muse, mutect2, varscan2
- SELP | c.2122C>T p.H708Y | Missense Mutation (SNP) | VAF 215/313 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1267389446; called by muse, mutect2, varscan2
- SIAH1 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 313/657 reads (48%) | catalogued as COSV99589469; called by muse, mutect2, varscan2
- SIX3 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 221/635 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1434383417; called by muse, mutect2, varscan2
- SLC22A13 | c.1075G>A p.G359S | Missense Mutation (SNP) | VAF 252/399 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528880884; called by muse, mutect2, varscan2
- SLC6A2 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 40/630 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs201586185, COSV54918713; called by muse, mutect2
- SMAD4 | c.725C>G p.S242* | Nonsense Mutation (SNP) | VAF 253/253 reads (100%) | catalogued as COSV61688361; called by muse, mutect2, varscan2
- SNAP91 | c.790A>G p.I264V | Missense Mutation (SNP) | VAF 115/336 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV52128396; called by muse, mutect2, varscan2
- SPP1 | c.430G>A p.E144K (on ENST00000395080 / NM_001040058.2; = p.E130K on NM_000582.2) | Missense Mutation (SNP) | VAF 244/245 reads (100%) | SIFT tolerated (0.67); PolyPhen benign (0.019); catalogued as rs201161531; called by muse, mutect2, varscan2
- STPG2 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 220/220 reads (100%) | catalogued as COSV54797550; called by muse, mutect2, varscan2
- TG | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 78/478 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372138161, COSV99601173; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.153del p.E51Dfs*72 | Frame Shift Del (DEL) | VAF 321/442 reads (73%) | catalogued as COSV52689092; called by mutect2, pindel, varscan2
- TTN | c.16165G>A p.E5389K (on ENST00000591111; = p.E4462K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 313/520 reads (60%) | PolyPhen benign (0.001); catalogued as rs376593556, COSV59960214; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA4B | c.436A>G p.K146E | Missense Mutation (SNP) | VAF 214/418 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs549672371, COSV67526198; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3691C>T p.R1231W | Missense Mutation (SNP) | VAF 263/413 reads (64%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs767522996; called by muse, mutect2, varscan2
- ZNF672 | c.995C>A p.T332K | Missense Mutation (SNP) | VAF 201/669 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV60637950; called by muse, mutect2, varscan2
- ACSM4 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 100/519 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- AKT2 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 238/370 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANAPC7 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 142/572 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ANKRD65 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 436/584 reads (75%) | SIFT tolerated (0.23); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ARMC12 | c.247G>A p.E83K (on ENST00000373866 / NM_001286574.2; = p.E110K on NM_145028.5) | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.098); called by muse, mutect2
- BECN2 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 348/526 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.088); called by muse, varscan2
- CAPN12 | c.798_804+8del p.X266_splice | Splice Site (DEL) | VAF 203/425 reads (48%) | called by mutect2, pindel, varscan2
- CCER1 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 497/776 reads (64%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CDCP1 | c.2002G>T p.V668F | Missense Mutation (SNP) | VAF 116/345 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2
- CDK10 | c.307G>T p.E103* (on ENST00000353379 / NM_052988.5; = p.E32* on NM_052987.4) | Nonsense Mutation (SNP) | VAF 302/302 reads (100%) | called by muse, mutect2, varscan2
- CLPTM1 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 266/684 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CLUH | c.1685A>G p.Y562C (on ENST00000435359; = p.Y600C on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 413/413 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP2 | c.263A>G p.D88G | Missense Mutation (SNP) | VAF 112/213 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- EML5 | c.5886G>A p.W1962* (on ENST00000380664; = p.W1970* on NM_183387.3) | Nonsense Mutation (SNP) | VAF 233/233 reads (100%) | called by muse, mutect2, varscan2
- EXPH5 | c.4436C>T p.S1479L | Missense Mutation (SNP) | VAF 142/281 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- F8 | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 301/301 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGL2 | c.902G>A p.R301K | Missense Mutation (SNP) | VAF 250/534 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FLT3 | c.2326G>C p.E776Q | Missense Mutation (SNP) | VAF 122/364 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.18); called by mutect2, varscan2
- FOXE1 | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 69/488 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- FOXL2 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 139/340 reads (41%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXO3 | c.94A>G p.T32A | Missense Mutation (SNP) | VAF 35/648 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2
- FRY | c.3973G>A p.E1325K | Missense Mutation (SNP) | VAF 268/439 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- FSIP2 | c.9077del p.N3026Tfs*10 | Frame Shift Del (DEL) | VAF 189/359 reads (53%) | called by mutect2, pindel, varscan2
- GADD45A | c.302T>G p.L101R | Missense Mutation (SNP) | VAF 148/609 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GZF1 | c.176T>A p.F59Y | Missense Mutation (SNP) | VAF 211/716 reads (29%) | SIFT tolerated (0.9); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- HAT1 | c.481A>C p.I161L | Missense Mutation (SNP) | VAF 168/269 reads (62%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- HSPBAP1 | c.347G>A p.R116K | Missense Mutation (SNP) | VAF 147/290 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HTR3A | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 130/273 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- IGKV1-12 | c.261T>G p.S87R | Missense Mutation (SNP) | VAF 118/804 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.165); called by muse, mutect2
- IL23R | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 235/318 reads (74%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LEMD2 | c.987C>G p.S329R | Missense Mutation (SNP) | VAF 248/414 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- MCF2L | c.1833G>C p.M611I (on ENST00000375608; = p.M579I on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 188/563 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSN | c.283C>G p.Q95E | Missense Mutation (SNP) | VAF 218/218 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- MUC5B | c.13776del p.V4593Cfs*45 | Frame Shift Del (DEL) | VAF 286/1240 reads (23%) | called by mutect2, pindel, varscan2
- MYPOP | c.560G>A p.C187Y | Missense Mutation (SNP) | VAF 428/695 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- NEFH | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 399/651 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- NLRP4 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 150/487 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- OR2M2 | c.420T>G p.I140M | Missense Mutation (SNP) | VAF 259/378 reads (69%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- OR56A5 | c.356T>C p.M119T | Missense Mutation (SNP) | VAF 118/485 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- PC | c.2155T>G p.S719A | Missense Mutation (SNP) | VAF 12/454 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2
- PCLO | c.7016T>A p.V2339E | Missense Mutation (SNP) | VAF 116/547 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PHRF1 | c.2032G>T p.E678* (on ENST00000264555 / NM_001286581.2; = p.E677* on NM_020901.4) | Nonsense Mutation (SNP) | VAF 361/882 reads (41%) | called by muse, mutect2, varscan2
- PPP1R13L | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 297/477 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF20 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 208/326 reads (64%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RXFP2 | c.1270G>C p.V424L | Missense Mutation (SNP) | VAF 150/435 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- SLC25A31 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SLC26A7 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 425/558 reads (76%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC43A3 | c.579C>G p.I193M | Missense Mutation (SNP) | VAF 150/320 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC5A3 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 228/432 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRRM4 | c.895A>C p.T299P | Missense Mutation (SNP) | VAF 243/483 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- STYX | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 190/191 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- SUZ12 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 195/195 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TEX45 | c.1508G>A p.S503N | Missense Mutation (SNP) | VAF 92/301 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMCC1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 203/352 reads (58%) | SIFT tolerated, low confidence (0.62); PolyPhen possibly damaging (0.483); called by mutect2, varscan2
- WASHC2C | c.3251G>C p.R1084T (on ENST00000336378; = p.R1063T on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 518/553 reads (94%) | SIFT tolerated (0.25); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- WWC2 | c.1819G>T p.D607Y | Missense Mutation (SNP) | VAF 34/441 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2
- ZNF28 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 135/513 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- ZNF468 | c.1476G>T p.E492D | Missense Mutation (SNP) | VAF 94/206 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, varscan2
- ZNF658 | c.1316T>A p.L439H | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.79); called by muse, mutect2
- ZNF692 | c.374C>G p.S125C | Missense Mutation (SNP) | VAF 342/530 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ZNF727 | c.1220G>T p.C407F | Missense Mutation (SNP) | VAF 104/497 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZNF729 | c.2780A>C p.K927T | Missense Mutation (SNP) | VAF 106/359 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- ADCY8 | c.3636C>T p.L1212= | Silent (SNP) | VAF 426/570 reads (75%) | called by muse, mutect2, varscan2
- ADK | c.645T>A p.S215= (on ENST00000286621; = p.S198= on NM_001123.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 298/298 reads (100%) | called by muse, mutect2, varscan2
- ATP13A4 | c.3495C>T p.P1165= | Silent (SNP) | VAF 207/395 reads (52%) | called by muse, mutect2, varscan2
- B4GALT3 | c.9G>A p.R3= | Silent (SNP) | VAF 261/412 reads (63%) | catalogued as rs778032228; called by muse, mutect2, varscan2
- CEACAM7 | c.420C>T p.Y140= | Silent (SNP) | VAF 193/296 reads (65%) | catalogued as rs782619214; called by muse, mutect2
- CES1 | c.987G>A p.L329= | Silent (SNP) | VAF 40/922 reads (4%) | catalogued as COSV62085588, COSV62087176; called by muse, mutect2
- CNTN5 | c.1926G>A p.L642= | Silent (SNP) | VAF 101/222 reads (45%) | catalogued as COSV54288538; called by muse, mutect2, varscan2
- DCHS1 | c.9772C>T p.L3258= | Silent (SNP) | VAF 193/711 reads (27%) | called by muse, mutect2, varscan2
- DCHS1 | c.411C>T p.N137= | Silent (SNP) | VAF 337/714 reads (47%) | catalogued as rs368674448; called by muse, mutect2, varscan2
- DDX50 | c.636A>G p.P212= | Silent (SNP) | VAF 157/158 reads (99%) | catalogued as COSV65293404; called by muse, mutect2, varscan2
- DIPK2B | c.315C>T p.S105= | Silent (SNP) | VAF 207/207 reads (100%) | catalogued as rs774043860; called by muse, mutect2, varscan2
- EOMES | c.466C>T p.L156= | Silent (SNP) | VAF 297/495 reads (60%) | catalogued as COSV55412057; called by muse, mutect2, varscan2
- ESS2 | c.1245G>T p.R415= | Silent (SNP) | VAF 314/588 reads (53%) | called by muse, mutect2, varscan2
- FDXACB1 | c.1842G>A p.E614= | Silent (SNP) | VAF 111/222 reads (50%) | catalogued as rs1555161821; called by muse, mutect2, varscan2
- GOLGA2 | c.2667C>T p.G889= | Silent (SNP) | VAF 505/505 reads (100%) | called by muse, mutect2, varscan2
- HCFC1 | c.3738C>T p.S1246= | Silent (SNP) | VAF 474/475 reads (100%) | catalogued as rs781962113; called by muse, mutect2, varscan2
- IL18RAP | c.687G>A p.V229= | Silent (SNP) | VAF 107/404 reads (26%) | called by muse, mutect2, varscan2
- KIF2A | c.738C>T p.I246= | Silent (SNP) | VAF 143/143 reads (100%) | called by muse, mutect2, varscan2
- LIPT2 | c.444C>T p.D148= | Silent (SNP) | VAF 182/368 reads (49%) | catalogued as rs376565466, COSV59526680; called by muse, mutect2, varscan2
- LRRC7 | c.3423C>T p.F1141= (on ENST00000651989 / NM_001370785.2; = p.F1108= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 253/352 reads (72%) | catalogued as rs769117658, COSV50436791; called by muse, mutect2, varscan2
- MUC16 | c.22740C>T p.I7580= | Silent (SNP) | VAF 127/368 reads (35%) | called by muse, mutect2, varscan2
- NTRK3 | c.159C>T p.L53= | Silent (SNP) | VAF 128/263 reads (49%) | catalogued as rs1193082361; called by muse, mutect2, varscan2
- OR5J2 | c.930C>T p.F310= | Silent (SNP) | VAF 65/145 reads (45%) | catalogued as COSV100399123; called by muse, mutect2, varscan2
- PLXNA2 | c.3492G>A p.L1164= | Silent (SNP) | VAF 230/316 reads (73%) | called by muse, mutect2, varscan2
- PRR3 | c.63C>T p.P21= | Silent (SNP) | VAF 226/614 reads (37%) | called by muse, mutect2, varscan2
- PSD3 | c.1539C>T p.I513= | Silent (SNP) | VAF 155/293 reads (53%) | catalogued as rs774525956, COSV58968886; called by muse, mutect2, varscan2
- RSPH1 | c.672C>T p.L224= | Silent (SNP) | VAF 322/546 reads (59%) | called by muse, mutect2, varscan2
- SETD1A | c.456C>G p.V152= | Silent (SNP) | VAF 349/728 reads (48%) | catalogued as COSV99353182; called by muse, mutect2, varscan2
- SLC2A5 | c.1077C>T p.L359= | Silent (SNP) | VAF 188/271 reads (69%) | catalogued as COSV101072678; called by muse, varscan2
- SLC35E2B | c.270C>G p.L90= | Silent (SNP) | VAF 8/37 reads (22%) | called by mutect2, varscan2
- SLC7A8 | c.630C>T p.C210= | Silent (SNP) | VAF 196/196 reads (100%) | called by muse, mutect2, varscan2
- SNAPC4 | c.1095C>T p.R365= | Silent (SNP) | VAF 132/447 reads (30%) | catalogued as rs752583567; called by muse, mutect2, varscan2
- SPG11 | c.4020C>T p.S1340= | Silent (SNP) | VAF 117/246 reads (48%) | catalogued as rs771193460; called by muse, mutect2, varscan2
- TENM4 | c.2904C>T p.I968= | Silent (SNP) | VAF 106/239 reads (44%) | called by muse, mutect2
- TMEM184C | c.891C>T p.I297= | Silent (SNP) | VAF 211/211 reads (100%) | catalogued as COSV56853236; called by muse, mutect2, varscan2
- TTLL2 | c.1107C>T p.L369= | Silent (SNP) | VAF 176/438 reads (40%) | called by muse, mutect2, varscan2
- TXNDC2 | c.321C>A p.S107= (on ENST00000306084 / NM_001098529.2; = p.S40= on NM_032243.6) | Silent (SNP) | VAF 61/423 reads (14%) | called by muse, mutect2, varscan2
- ZCWPW2 | c.595C>T p.L199= | Silent (SNP) | VAF 33/276 reads (12%) | called by muse, mutect2, varscan2
- ZNF749 | c.99C>T p.H33= | Silent (SNP) | VAF 25/459 reads (5%) | called by muse, mutect2
- AL109984.1 | n.186+1490G>A | Intron (SNP) | VAF 161/642 reads (25%) | catalogued as rs1353194712; called by muse, mutect2, varscan2
- ANKRD33 | c.-100G>C | 5'UTR (SNP) | VAF 343/526 reads (65%) | called by muse, mutect2, varscan2
- CA6 | c.259+2163G>C | Intron (SNP) | VAF 217/288 reads (75%) | catalogued as COSV101077690; called by muse, mutect2, varscan2
- FGFR1 | c.937-1172G>A | Intron (SNP) | VAF 110/265 reads (42%) | called by muse, mutect2, varscan2
- MDH1 | c.3+286G>A | Intron (SNP) | VAF 97/310 reads (31%) | called by muse, mutect2, varscan2
- NPAP1L | n.361A>C | RNA (SNP) | VAF 90/431 reads (21%) | called by muse, mutect2
- POLR2M | c.113+94G>A | Intron (SNP) | VAF 230/441 reads (52%) | called by muse, varscan2
- TTC17 | c.2252-7148G>A | Intron (SNP) | VAF 76/159 reads (48%) | called by muse, mutect2, varscan2
- UNC45A | chr15:90934429 C>T | 5'Flank (SNP) | VAF 154/512 reads (30%) | called by muse, mutect2, varscan2
- ZNF418 | c.*654C>T | 3'UTR (SNP) | VAF 224/382 reads (59%) | called by muse, mutect2, varscan2
